Somatic mutation profile of tumor specimen TARGET-50-PAKVET-01A (aliquot TARGET-50-PAKVET-01A-01D) from TARGET case TARGET-50-PAKVET, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.1 years (405 days).
Specimen TARGET-50-PAKVET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62b709c2-8e1f-4b59-9d27-27f8ea32278b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKVET-11A (Solid Tissue Normal), aliquot TARGET-50-PAKVET-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4871704-a979-40d9-8ad3-b51c5a1432dc

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN7A | c.4648T>C p.F1550L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, varscan2
- IQSEC2 | c.4080C>T p.P1360= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1280198177; called by muse, mutect2
- SLC12A3 | c.2472G>A p.S824= (on ENST00000563236 / NM_001126108.2; = p.S833= on NM_000339.3) | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as rs780175485; called by muse, mutect2, varscan2
